Somatic mutation profile of tumor specimen TCGA-D7-6815-01A (aliquot TCGA-D7-6815-01A-11D-1882-08) from TCGA case TCGA-D7-6815, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.7 years (25,811 days).
Specimen TCGA-D7-6815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2428442e-aa98-447f-9e90-a2a1fd1f8cf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6815-10A (Blood Derived Normal), aliquot TCGA-D7-6815-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d2562b9-47da-4c6f-9aac-529f8c3c27e7

The open-access MAF lists 142 somatic variants for this specimen: 94 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 42, Nonsense Mutation 10, Frame Shift Del 5, Frame Shift Ins 4, Intron 3, Splice Region 2, In Frame Ins 2, In Frame Del 2, 3'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RASA1 | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs863223718, CM1311709, COSV57191662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 61/71 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACAN | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs757439227, COSV61367069; called by muse, mutect2, varscan2
- ADGRF5 | c.3911C>T p.S1304F | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51933037, COSV51938554; called by muse, mutect2, varscan2
- AGMO | c.416A>T p.N139I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61121315; called by muse, mutect2, varscan2
- ARHGAP18 | c.967dup p.C323Lfs*32 | Frame Shift Ins (INS) | VAF 17/104 reads (16%) | catalogued as rs1292136331; called by mutect2, pindel, varscan2
- ARMC12 | c.212G>A p.R71Q (on ENST00000373866 / NM_001286574.2; = p.R98Q on NM_145028.5) | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs761913031, COSV55361335; called by muse, mutect2, varscan2
- ATP1A2 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs781474239, COSV63405386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICC1 | c.2518A>G p.K840E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV54065940; called by muse, mutect2, varscan2
- C2orf16 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV62677591; called by muse, mutect2, varscan2
- CACHD1 | c.2727G>A p.A909= | Splice Region (SNP) | VAF 12/144 reads (8%) | catalogued as rs1321013049, COSV51558514; called by muse, mutect2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2, varscan2
- CAD | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 65/149 reads (44%) | catalogued as rs771348417, COSV53023901; called by muse, mutect2, varscan2
- CCDC153 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs370540178, COSV59541900; called by muse, mutect2, varscan2
- CD93 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138932459; called by muse, mutect2, varscan2
- CRISP3 | c.656G>T p.G219V (on ENST00000371159 / NM_001368123.1; = p.G201V on NM_006061.4) | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53822407; called by muse, mutect2, varscan2
- CYLC2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66339021; called by muse, mutect2
- DFFA | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV65478059; called by muse, mutect2, varscan2
- DNAH11 | c.7822C>A p.Q2608K | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.69); catalogued as COSV60974067; called by muse, mutect2, varscan2
- DPY19L2 | c.1614T>G p.F538L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV61044953; called by muse, mutect2
- EIF4G1 | c.2125C>T p.R709* (on ENST00000346169 / NM_198241.3; = p.R514* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 101/416 reads (24%) | catalogued as COSV59988856; called by muse, mutect2, varscan2
- ETV1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.88); catalogued as rs748182764, COSV54143260, COSV54149188; called by muse, mutect2, varscan2
- EXOC7 | c.1919C>T p.P640L (on ENST00000335146 / NM_001145297.4; = p.P558L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs781658922, COSV58035345; called by muse, mutect2, varscan2
- FAM189B | c.468A>C p.K156N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV56946973; called by muse, mutect2, varscan2
- FASTK | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.033); catalogued as COSV52541682; called by muse, mutect2, varscan2
- FAT2 | c.10096C>A p.L3366I | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as rs145145475, COSV55827004; called by muse, mutect2, varscan2
- FGF12 | c.664C>T p.R222C (on ENST00000454309 / NM_021032.5; = p.R160C on NM_004113.6) | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1427870966, COSV53170192; called by muse, mutect2, varscan2
- FLG | c.8344G>A p.G2782S | Missense Mutation (SNP) | VAF 96/1220 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs748391293, COSV64246443; called by muse, mutect2
- GOLGA4 | c.4925G>T p.R1642I | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV62713019; called by muse, mutect2, varscan2
- GRIA1 | c.2599G>T p.A867S | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs139474308, COSV53615053; called by muse, mutect2, varscan2
- ILDR2 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV54834510; called by muse, mutect2, varscan2
- ITPR1 | c.1033C>T p.R345W (on ENST00000354582; = p.R330W on NM_002222.7) | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs369055445, COSV56970267; called by muse, mutect2, varscan2
- JAK2 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67651292; called by muse, mutect2
- KCNH6 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs200824708, COSV59004570, COSV59006712; called by muse, mutect2, varscan2
- KDM4A | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as COSV64960365; called by muse, mutect2, varscan2
- KIAA1210 | c.2072C>A p.A691D | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV68179302; called by muse, mutect2, varscan2
- KIDINS220 | c.5285G>C p.G1762A | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV56757747; called by muse, mutect2, varscan2
- KLHL7 | c.949A>G p.T317A (on ENST00000339077 / NM_001031710.3; = p.T269A on NM_018846.5) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59163827; called by muse, mutect2, varscan2
- MBD6 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs1262962090; called by muse, mutect2, varscan2
- MCHR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs267600747, COSV56000697; called by muse, mutect2
- MED12L | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs774424420, COSV56370763; called by muse, mutect2, varscan2
- MTBP | c.2407G>C p.A803P | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV59965571; called by muse, mutect2, varscan2
- OR10C1 | c.394C>T p.R132C (on ENST00000622521; = p.R130C on NM_013941.3) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1003810361, COSV65822310; called by muse, mutect2, varscan2
- PCDHA4 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs376395074, COSV63543797; called by muse, mutect2, varscan2
- PDZRN4 | c.1375G>C p.E459Q (on ENST00000402685 / NM_001164595.2; = p.E201Q on NM_013377.4) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV54212318, COSV54212676, COSV54217178; called by muse, mutect2
- PHLDB2 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs772453408, COSV67315038; called by muse, mutect2, varscan2
- PLEKHG4 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58574465; called by muse, mutect2, varscan2
- PRKAG2 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 205/424 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.096); catalogued as rs540525001, COSV55237918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF40B | c.2084G>A p.G695D (on ENST00000380281; = p.G682D on NM_012272.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs768250601, COSV53306230; called by muse, mutect2, varscan2
- PSMG1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178582445, COSV59001144; called by muse, mutect2, varscan2
- RDH5 | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV57677160; called by muse, mutect2
- RFK | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV65061203; called by muse, mutect2, varscan2
- SACS | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.246); catalogued as COSV66537971; called by muse, mutect2
- SEMA3F | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137935899; called by muse, mutect2, varscan2
- SGF29 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs1207027680, COSV57682840; called by muse, mutect2, varscan2
- SMAD4 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV61690085; called by muse, mutect2, varscan2
- SMG5 | c.1133G>A p.S378N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV62437157; called by muse, mutect2, varscan2
- SPATA7 | c.985T>C p.W329R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50419707; called by muse, mutect2, varscan2
- SPTB | c.2609G>T p.W870L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as COSV67634316; called by muse, mutect2, varscan2
- SUGP2 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1157362653, COSV54180166; called by muse, mutect2, varscan2
- SYNE1 | c.14080T>A p.F4694I (on ENST00000367255 / NM_182961.4; = p.F4623I on NM_033071.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV55068563; called by muse, mutect2, varscan2
- TAFA2 | c.279A>T p.K93N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV69185774; called by muse, mutect2
- TAOK1 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55596577; called by muse, mutect2, varscan2
- TNFAIP2 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV60695733; called by muse, mutect2, varscan2
- TOP1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV63695611; called by muse, mutect2, varscan2
- TRAK1 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375388142; called by muse, mutect2, varscan2
- UNC5CL | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV55111405; called by muse, mutect2, varscan2
- ZAN | c.2927T>G p.L976R | Missense Mutation (SNP) | VAF 118/235 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.221); catalogued as COSV61813959; called by muse, mutect2, varscan2
- ZC3H18 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV56327238; called by muse, mutect2, varscan2
- ZC3H4 | c.3880T>C p.F1294L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53416074; called by muse, mutect2, varscan2
- ZNF282 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs1458765910, COSV50482436; called by muse, mutect2, varscan2
- ZNF362 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs755697341, COSV65031366; called by muse, mutect2, varscan2
- ZNF547 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56581631; called by muse, mutect2, varscan2
- ZSCAN10 | c.1984C>T p.Q662* (on ENST00000252463; = p.Q717* on NM_032805.3) | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52970089; called by muse, mutect2, varscan2
- AGAP7P | n.498C>A | Splice Region (SNP) | VAF 12/112 reads (11%) | called by muse, varscan2
- COL6A3 | c.4194dup p.S1399Qfs*33 | Frame Shift Ins (INS) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- DCLK1 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2
- E2F8 | c.1235del p.N412Ifs*37 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- KIF26A | c.1849_1850insCGA p.E616_K617insT | In Frame Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- LCMT2 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLLT6 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 46/1182 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); called by muse, mutect2
- MRM1 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAF1 | c.738_740del p.I246_R247delinsM | In Frame Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- PEG3 | c.3933_3947delinsG p.Y1311* | Nonsense Mutation (DEL) | VAF 21/87 reads (24%) | called by pindel, varscan2*
- PLEKHO2 | c.139del p.Q47Sfs*83 | Frame Shift Del (DEL) | VAF 97/268 reads (36%) | called by mutect2, pindel, varscan2
- PTN | c.123del p.V42* | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, varscan2
- PTPN7 | c.833del p.P278Rfs*11 (on ENST00000495688; = p.P317Rfs*11 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- SAFB2 | c.106_120del p.I36_A40del | In Frame Del (DEL) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- SEPTIN9 | c.1011del p.K338Rfs*19 (on ENST00000427177 / NM_001113491.2; = p.K320Rfs*19 on NM_006640.4) | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1234dup p.Y412Lfs*17 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- SNAI3 | c.581_583dup p.S194_L195insR | In Frame Ins (INS) | VAF 46/181 reads (25%) | called by mutect2, pindel, varscan2
- WNK2 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- ZFP1 | c.856_857insCACAG p.H286Pfs*60 | Frame Shift Ins (INS) | VAF 24/55 reads (44%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.2277G>A p.T759= (on ENST00000289968 / NM_001006634.3; = p.T681= on NM_018054.6) | Silent (SNP) | VAF 54/215 reads (25%) | catalogued as rs776541771, COSV51510875; called by muse, mutect2, varscan2
- BAIAP3 | c.3258C>T p.S1086= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs375793316; called by muse, mutect2, varscan2
- BCHE | c.1620G>A p.T540= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs774356916, COSV52256999; called by muse, mutect2, varscan2
- BSN | c.4704G>A p.Q1568= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV56525198; called by muse, mutect2, varscan2
- CA4 | c.594G>A p.T198= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1013826647, COSV56281699; called by muse, mutect2, varscan2
- CCDC116 | c.279G>A p.A93= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs778183454, COSV53038587; called by muse, mutect2, varscan2
- CCDC171 | c.3345G>T p.L1115= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV52649767; called by muse, mutect2, varscan2
- CIBAR2 | c.177C>T p.S59= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs771669601, COSV73320556; called by muse, mutect2, varscan2
- CLVS1 | c.408C>T p.Y136= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs758197932, COSV57981019, COSV57981660; called by muse, mutect2, varscan2
- CREBBP | c.5451G>A p.P1817= | Silent (SNP) | VAF 44/195 reads (23%) | catalogued as rs373848722; called by muse, mutect2, varscan2
- CRYAB | c.102G>A p.E34= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV57052263; called by muse, mutect2, varscan2
- CTLA4 | c.411G>A p.P137= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs188862082, COSV55592978; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCLK1 | c.906C>A p.S302= | Silent (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2
- DEUP1 | c.591G>A p.Q197= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1291715309, COSV53215493; called by muse, mutect2, varscan2
- DOCK4 | c.4140G>A p.L1380= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV70240488, COSV70241758; called by muse, mutect2, varscan2
- ELF1 | c.756G>A p.K252= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as COSV53501745; called by muse, mutect2, varscan2
- FAM83H | c.1866C>T p.A622= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs564413971, COSV66354432; called by muse, mutect2
- GH2 | c.30C>T p.L10= | Silent (SNP) | VAF 52/203 reads (26%) | catalogued as rs1332817107, COSV60427560; called by muse, mutect2, varscan2
- HIBCH | c.138G>A p.T46= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs561975623, COSV62892784; called by muse, mutect2, varscan2
- IZUMO2 | c.64C>T p.L22= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs763489081, COSV53231092; called by muse, mutect2, varscan2
- KIF1B | c.3456G>A p.T1152= (on ENST00000377086 / NM_001365952.1; = p.T1106= on NM_015074.3) | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs574168097, COSV55813926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAS1L | c.105A>C p.P35= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56708651; called by muse, mutect2, varscan2
- LBP | c.105C>T p.T35= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs1229981292, COSV54142693; called by muse, mutect2
- LCMT2 | c.267C>T p.G89= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs762817315, COSV99980044; called by muse, mutect2, varscan2
- MATN2 | c.927C>T p.Y309= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as rs372237220; called by muse, mutect2, varscan2
- MN1 | c.2784G>A p.S928= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1219191918, COSV56555891, COSV56562284; called by muse, mutect2, varscan2
- NLRC3 | c.1302G>A p.P434= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs746225755, COSV57094453; called by muse, mutect2, varscan2
- NPPA | c.210G>A p.A70= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs764844383, COSV56742439; called by muse, mutect2, varscan2
- NR0B1 | c.621G>A p.P207= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1421457426, COSV66764662; called by muse, mutect2, varscan2
- OBSCN | c.4542C>T p.C1514= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs372583837; called by muse, mutect2, varscan2
- OR8H1 | c.534C>T p.C178= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs374019056; called by muse, mutect2, varscan2
- PCDHA6 | c.288C>T p.C96= | Silent (SNP) | VAF 134/306 reads (44%) | catalogued as rs782510418, COSV65350472; called by muse, mutect2, varscan2
- PCDHGA6 | c.1908C>T p.D636= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs770239249, COSV53896503; called by muse, mutect2, varscan2
- PXDN | c.1263C>G p.V421= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV53243685; called by muse, mutect2
- SEMA3D | c.2037G>T p.L679= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV52401535; called by muse, mutect2, varscan2
- SERPINB4 | c.294A>G p.A98= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs772872268, COSV61985875; called by muse, mutect2, varscan2
- SREBF2 | c.1257G>T p.L419= | Silent (SNP) | VAF 73/325 reads (22%) | catalogued as COSV63332180; called by muse, mutect2, varscan2
- TECPR2 | c.3774T>A p.I1258= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV63973323; called by muse, mutect2, varscan2
- TGFBR1 | c.858A>T p.G286= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV66626571; called by muse, mutect2, varscan2
- TSR1 | c.1128G>A p.L376= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV52160799; called by muse, mutect2, varscan2
- TTK | c.2526T>C p.H842= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs1373913644, COSV57886037; called by muse, mutect2, varscan2
- XKRX | c.357G>A p.K119= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as COSV60707366; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506282 C>G | 3'Flank (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- MIR522 | n.79G>A | RNA (SNP) | VAF 46/100 reads (46%) | catalogued as rs377484755; called by muse, mutect2, varscan2
- MRC1 | c.917-116A>G | Intron (SNP) | VAF 9/161 reads (6%) | catalogued as COSV99519423; called by muse, mutect2
- PIK3R6 | c.-217C>A | 5'UTR (SNP) | VAF 43/51 reads (84%) | catalogued as COSV100266669, COSV61004731; called by muse, mutect2, varscan2
- PTBP1 | c.892+343G>A | Intron (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- STEAP3 | c.-77+7123G>A | Intron (SNP) | VAF 13/56 reads (23%) | catalogued as rs761921420, COSV100713384; called by muse, mutect2, varscan2
